Surgical pathology report (de-identified scan), TCGA case TCGA-12-5301, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-5301-01A (Primary Tumor).

Patient: [REDACTED]

AP Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain neoplasm. [REDACTED] with middle frontal gyrus lesion. [REDACTED] In [REDACTED], he noted sudden [REDACTED]. He eventually went on to have a scan of his brain which showed a lesion in the left frontal lobe.

[REDACTED] MRI report [REDACTED]: Preoperative brain lab MRI reveals fiducial markers in place. Again seen is a rim-enhancing lesion within the left frontal lobe. Overall size of the enhancing lesion has not significantly changed. However, when compared to the prior study there has been interval decrease in the enhancement with decreased surrounding edema. No new enhancing foci are identified. There has been interval decrease in the mass effect on the left lateral ventricle. No evidence of midline shift. No abnormal extra-axial fluid collections.

GROSS EXAMINATION:

A. "Brain tissue (Afl)", received fresh for frozen section and placed in formalin at [REDACTED] is a 4 x 2.5 x 1.3 cm aggregate of soft, gray-tan tissue and a 1.3 x 1.3 x 1.2 cm fragment of red-brown blood clot. A portion of the soft tissue was frozen as representative Afl and the frozen section remnant submitted in A1. Additional sections of the specimen including the blood clot are submitted in A2-4.

[REDACTED] to [REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": Afl- (representative)- glioma, high-grade [REDACTED].

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant small cell astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis.

DIAGNOSIS:

A. BRAIN TISSUE; CRANIOTOMY:

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED] D.

Electronically signed: [REDACTED]

Performed by: [REDACTED]

Attending MD: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 72d50a57-ea54-4cb3-86c4-5d1b1bc9834b (TCGA-12-5301.F306D9F8-B08A-4B45-A016-7C1FA97F700D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).